Surgical pathology report (de-identified scan), TCGA case TCGA-XK-AAJT, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-XK-AAJT-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

****ADDENDUM PRESENT****

Patient Name: [REDACTED]
Clinic Number: [REDACTED]
Date of Birth: [REDACTED] Age: [REDACTED] Gender: M
Requested By: [REDACTED]

Accession #:
Procedure Date:
Received Date:
Account #: [REDACTED]
Report Signed:

Final Diagnosis:

A. Prostate with bilateral lymph nodes, radical prostatectomy with lymphadenectomy: Prostatic adenocarcinoma (see synoptic report below).

Procedure: Radical prostatectomy with lymphadenectomy.

Histologic type: Acinar adenocarcinoma.

Histologic grade:

Primary pattern: 4 Secondary pattern: 3 Tertiary pattern: 5
Total Gleason Score: 7; with minor pattern 5.

Tumor quantitation: Tumor involves the peripheral zone bilaterally in the lower third of the gland.

Extraprostatic extension: Present, focally on right side lower third.

Margins: Surgical margins focally positive on left side in apex (over a 1-mm contiguous length). Where ink touches tumor, there is no capsule identifiable (extraprostatic spread in the prostate apex is difficult to define given the anatomy of this region).

Lymph-vascular invasion: Not identified.

Perineural invasion: Present.

Seminal vesicle invasion: Absent.

Treatment effect on carcinoma: Not identified.

Lymph nodes: Four lymph nodes negative for metastatic carcinoma.

Additional pathologic findings: Multifocal high-grade prostatic intraepithelial neoplasia is present.

Ancillary studies: DNA ploidy analysis is pending on block A3.

Pathologic staging: pT3a.

Biorepository sample (if applicable): Positive for tumor, greater than 90% of the sample contains carcinoma.

Block(s) containing malignancy suitable for additional testing: A3, A4, A7, A8.

ICD O 3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
7/23/25/14

Interpreted by:

Report electronically signed out by

Transcribed by:

ADDENDA:

Paraffin embedded tumor tissue was sent to
([REDACTED]) interpreted ([REDACTED]) follows:

for DNA ploidy by DIA studies. The report

[page 2 of 4]
Source: Prostate, Left Apex, Radical Prostatectomy, block

A3

Results:

The cancer cells are DNA aneuploid.

DNA ploidy test results have been validated by our laboratory for formalin-fixed, paraffin embedded tissue sections. Analysis was performed using the instrument, which determined DNA ploidy status by comparing the DNA content of tumor cells and control cells (selected by operator). This test was developed and its performance characteristics determined by the U.S. Food and Drug Administration. This test has not been cleared or approved.

Proliferation index (MIB-1) = 4.45%.

Ki-67 Antigen immunohistochemical test results are valid for paraffin embedded tissue sections fixed in formalin. Testing is performed using the MIB-1 clone and a polymer-based detection system. Image collection and analysis is performed using the instrument. The renders the percentage of positive staining tumor nuclei (tumor selected by operator).

Transcribed by

Signed by

Clinical Information:

Prostate cancer.

Specimen(s):

A: Prostate with bilateral lymph nodes

Gross Description:

Performed by Pathologist's Assistant

A1A2A3A4A5A6A7A8A9A10A11A12A13A14A15A16A17A18A19A20A21A22

Received fresh labeled and "Prostate and lymph nodes".

Procedure: Radical prostatectomy

Prostate size: Weight: 72 grams; Dimensions: 4.5 x 4 x 4 cm; Seminal vesicles: 3.5 x 1 x 0.5 cm.

Gross notes: Grossly evident tumor: None.

Symmetry: Asymmetric, right slightly larger.

Gross nodular hyperplasia: Extensive.

Gross capsular bulge/defect: None.

Inking: left-black, right-blue

Biorepository sample collected: Yes. See block key.

Lymph nodes: Five possible lymph nodes from 0.8 cm to 1.3 cm.

Block key for specimen A:

- 1) proximal urethral margin
- 2) distal urethral margin
- 3) left apical margin, perpendicular
- 4) right apical margin, perpendicular

[page 3 of 4]
- 5) left bladder neck margin, perpendicular
6) right bladder neck margin, perpendicular
7) left apical prostate
8) right apical prostate
9) left mid prostate
10) right mid prostate
11) left mid prostate
12) right mid prostate
13) left base of prostate
14) right base of prostate
15) left seminal vesicle
16) right seminal vesicle

Additional sections:

- 17) mirror image of tissue submitted for research
18-22) one bisected lymph node each.

*Pw TSS dx discrepancy from,
TC6A tumor Gleason is 4+4*

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by
They have not been cleared or approved by the U. S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is
not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as
qualified to perform high complexity clinical laboratory testing

END OF REPORT

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Issue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

id	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Adenocarcinoma Gleason 4+3 = 7	Provide the diagnosis/histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	adenocarcinoma Gleason 4+4 = 8	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Pathology report Gleason score is 7.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnosis.

Signature

Date

Source: NCI Genomic Data Commons file b4ab3f41-956a-4aeb-af2d-7eeb80bc7917 (TCGA-XK-AAJT.7596C336-6BF6-4188-9C8B-90C0EC840911.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).